Surgical pathology report (de-identified scan), TCGA case TCGA-06-0876, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0876-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

06-0876

CLINICAL HISTORY

[REDACTED] with headache and left-sided weakness has right parietal mass, necrotic, with peripheral enhancement and edema with mass effect.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, Right parietal biopsy
B: Brain, right parietal biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parietal, excisional biopsy and excision:
1. Malignant glioma.
2. MIB-1 proliferation index: 6% to 30%.
See Comment.

COMMENT

The specimen is a portion of cerebrum extensively effaced by a small cell glial neoplastic proliferation with nuclear anaplasia, brisk mitotic activity, microvascular proliferation, and zones of tumor necrosis. In part B there is extensive necrosis.

The neoplasm is a high histological grade glioma, consistent with a small cell glioblastoma. There is a possibility of an oligodendroglial component.

Additional testing may further characterize the neoplasm.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

[page 2 of 4]
Results-Comments

Testing was done on tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

1

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p is NOT detected.

There is loss of heterozygosity in only one of the markers (PLA2G4C) on chromosome arm 19q suggestive of partial deletion.

Informative loci are:

D1S1592, D1S468, D1S496

D19S412, PLA2G4C, D19S606, D19S1182

Results-Comments

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[page 3 of 4]
TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

INTRA-OPERATIVE CONSULTATION

A.

Brain, Right parietal biopsy, touch prep and smears: High histological grade glioma, astrocytic. Touch preparation smears performed at and results reported to the Physician of Record.

GROSS DESCRIPTION

A.

"Right parietal," received fresh, one fragment, 0.9 cm. Across. Semi firm, glistening, grey. In total, A1.

B.

"Right parietal," several fragments, soft, focally hemorrhagic, 2.0 cm. across in aggregate. In total, B1 and B2.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates focal sparse gliofibrillarity, and focal areas with prominent gemistocytes, some probably reactive, neoplastic, and some minigemistocyte-like. About 10% of neoplastic cells over express the p53 protein. With the MIB-1 the proliferation index ranges between 6% and 30% in the more active areas.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain, Right parietal biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		
H/E x 1		1		
H/E x 1		1		
MGMT x 1		1		
Thanks				Please, run LOH, 1p, 19q.
MIB1-DA x 1		1		
NeuN x 1		1		
P53DO7 x 1		1		

[page 4 of 4]
Synap-DA x 1 1
TPS H/E x 1 1
H/E x 1 2

Part B: Brain, right parietal biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
mGFAP-DA x 1	2		
H/E x 1	2		
MIB1-DA x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 06035f59-5d5d-456c-b17d-5a4b977dcc1a (TCGA-06-0876.64D0B1FE-8C45-4352-B557-C7E8D075A26B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).